Gene-level copy-number profile of tumor specimen HTMCP-03-06-02046-01A from CGCI case HTMCP-03-06-02046, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G1.
Specimen HTMCP-03-06-02046-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 04ac00ca-4686-4c2f-86a8-425972e2d20e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02046-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,251 have no estimate.
https://portal.gdc.cancer.gov/files/879417f6-fcc1-4d60-9c73-5e369688b5a8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 19; copy number 2: 4,749; copy number 3: 14,755; copy number 4: 26,678; copy number 5: 3,747; copy number 6: 8,334; copy number 7: 83; copy number 23: 1; copy number 28: 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.
- chr19:1,177,558–1,228,431, 2 genes (within-gene range 0–2): STK11, HMGB2P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,286,689–89,295,455, 2 genes, copy number 28: IGKV1-35, IGKV2-36.
- chr16:32,475,051–32,478,250, 1 gene, copy number 23: ABCD1P3.

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
